Somatic mutation profile of tumor specimen TCGA-WB-A81P-01A (aliquot TCGA-WB-A81P-01A-11D-A35I-08) from TCGA case TCGA-WB-A81P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 73.6 years (26,867 days).
Specimen TCGA-WB-A81P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d3d49f0-ce69-4f88-ab30-7dc8ccee805f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81P-10A (Blood Derived Normal), aliquot TCGA-WB-A81P-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f7cd18b-29a0-4795-a8c4-caa2ce117cef

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9A | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1219693099, COSV58772477; called by muse, mutect2
- ATR | c.806T>C p.F269S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1379595419; called by muse, mutect2, varscan2
- EHMT1 | c.2548G>C p.G850R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71778021; called by muse, mutect2, varscan2
- IL15RA | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66092730; called by muse, mutect2
- MARK4 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372480258; called by muse, mutect2, varscan2
- TRRAP | c.9598G>A p.A3200T (on ENST00000359863 / NM_001244580.1; = p.A3171T on NM_003496.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755025267; called by muse, mutect2
- ASRGL1 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CEP250 | c.7262G>A p.S2421N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTH | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLM2 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- LLGL1 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALT1 | c.1911+1G>A p.X637_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- NF1 | c.7229_7232del p.V2410Efs*7 (on ENST00000358273 / NM_001042492.3; = p.V2389Efs*7 on NM_000267.3) | Frame Shift Del (DEL) | VAF 7/9 reads (78%) | called by mutect2, varscan2
- PRICKLE2 | c.290C>T p.P97L (on ENST00000295902; = p.P41L on NM_198859.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETBP1 | c.2147G>A p.S716N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TOX3 | c.1163T>A p.L388* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- ZNF507 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- DNAH17 | c.3996C>T p.A1332= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- IGLL1 | c.519C>T p.Y173= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1161500544; called by muse, mutect2, varscan2
